Surgical pathology report (de-identified scan), TCGA case TCGA-ZM-AA0D, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site University of Ulm, specimen TCGA-ZM-AA0D-01A (Primary Tumor).

ICD O 3
Seminoma NOS 9061/3
Site @ Testis NOS C62.9
JW 3/3/14

Date of procurement:

Pathohistological diagnosis

Seminoma, right testicle

Description

A testicle, size 5x4x3 cm with 8.5 cm long funiculus was received. On the surface we find 2 surgical cuts, 5 and 3 cm long, cut with sutures. On the cut we see numerous gray-white, finely limited nodes between 0.7 and 1.5 cm in diameter.

Histologically, the tumor is made of solid tumor cell seats with round and oval bright nuclei containing nucleolus and medium abundant bright and pink cytoplasm. Surrounding the tumor cells clusters we see connecting tissue permeated by lymphocytes.

The tumor is not present in funiculus nor in rete testis.

Source: NCI Genomic Data Commons file dad9df8b-ee8f-4d65-bd55-4f9a84ee6d2e (TCGA-ZM-AA0D.BD545A62-1073-4A83-BE63-6A2835CD4365.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).